CCDI case PBCJIN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/22a36acc-1695-4ca6-83fc-db5f95a61e8f

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: External ear; Age at diagnosis: 1.4 years (529 days).

Biospecimens (3 samples)
- Sample 0DU07D: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU07L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU07Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
